Surgical pathology report (de-identified scan), TCGA case TCGA-06-5410, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5410-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-5410

Surgical Pathology Report

=====

CLINICAL HISTORY

Right parietal brain lesion

OPERATIVE DIAGNOSES

Operation/Specimen: A: Right brain mass, excision biopsy
B: Right brain mass, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, right parietal lesion, biopsy: Glioblastoma (WHO Grade IV) (see comment).

B. Brain, right parietal lesion, excision: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis. Sections show a densely cellular glial neoplasm with extensive areas of necrosis. Marked acute inflammatory response is noted within the necrotic areas. Perivascular lymphocytic infiltrates are also present, as are other reactive changes. The tumor cells show moderate nuclear pleomorphism with occasional bizarre nuclei.

Several mitotic figures are noted. There is endothelial cell hypertrophy, often associated with fibrin thrombi.

Grocott methylene silver stain is negative for fungus. Gram stain is negative for bacterial microorganisms. Immunostains for GFAP, S100 and CD56 are strongly positive within the neoplastic cells. KP1 (CD68) is positive only in occasional histiocytes. The tumor cells are negative for pancytokeratin and cytokeratin AE1/AE3.

The tumor cell nuclei are diffusely p53 positive. The Ki-67 labelling index is

[page 2 of 3]
approximately 25%. Positive and negative controls show appropriate reactivity.

INTRA-OPERATIVE CONSULTATION

A. Right brain mass, excision biopsy: Infiltrating glioma. Frozen section and smears performed on specimen A1 at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A. Right brain mass, excision biopsy:

CONTAINER LABEL: right brain mass.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 0.8 x 0.3 x 0.5 cm white and grey tan soft tissue fragment for intraoperative consultation.

Sections: A1 Frozen section remnant, all submitted; A2 rest of tissue, all submitted.

B. Right brain mass, excision biopsy:

CONTAINER LABEL: brain mass.

FIXATIVE: Formalin. NO. PIECES: num. SIZE/VOL: 35 x 20 x 10 mm aggregate of pink-tan to gray-white soft focally hemorrhagic tissue fragments.

CASSETTES:

3, [REDACTED]

ICD-9(s):

239.6 239.6

Histo Data

Part A: Right brain mass, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	

[page 3 of 3]
Part B: Right brain mass, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
CD56-NO x 1	2 [REDACTED]
mGFAP-DA x 1	2 [REDACTED]
Gram x 1	2 [REDACTED]
Grocott x 1	2 [REDACTED]
H/E x 1	2 [REDACTED]
KeratinSu x 1	2 [REDACTED]
AE1/AE3 x 1	2 [REDACTED]
KP1-DA x 1	2 [REDACTED]
MIB1-DA x 1	2 [REDACTED]
P53DO7 x 1	2 [REDACTED]
SL00-DA x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]

*** End of Report ***

Source: NCI Genomic Data Commons file 0c4a903d-aab5-4f08-b896-ad8d028ae01c (TCGA-06-5410.CAC1B60D-9CA3-4196-9E74-FBA7A5490F2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).